Somatic mutation profile of tumor specimen ALCH-AE98-TTP1-A (aliquot ALCH-AE98-TTP1-A-2-0-D-A627-36) from ALCHEMIST case ALCH-AE98, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.0 years (20,072 days).
Specimen ALCH-AE98-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 818105d4-7338-4b99-987d-296f406b78f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE98-NB1-A (Blood Derived Normal), aliquot ALCH-AE98-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f7e661b-aa1c-4403-8386-f4105906e855

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 2, Intron 2, In Frame Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 77/1329 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 30/368 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ANKS1B | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1237831555; called by muse, mutect2
- BMP5 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 29/711 reads (4%) | catalogued as COSV63702572; called by muse, mutect2
- KLLN | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs753061420; called by muse, mutect2
- LHX8 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV53954991, COSV99634399; called by muse, mutect2
- MBP | c.611G>A p.G204D (on ENST00000355994 / NM_001025101.2; = p.G97D on NM_002385.3) | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs763871565, COSV100592648; called by muse, mutect2
- ACO2 | c.722G>A p.W241* | Nonsense Mutation (SNP) | VAF 107/525 reads (20%) | called by muse, mutect2, varscan2
- CYB5A | c.259-8C>T | Splice Region (SNP) | VAF 20/580 reads (3%) | called by muse, mutect2
- CYP4F12 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GALNT11 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); called by muse, mutect2
- INF2 | c.3289T>G p.L1097V | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); called by muse, mutect2
- INO80D | c.1065A>C p.Q355H | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- MAGEB3 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- SERPINE2 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.041); called by muse, mutect2
- TRIM46 | c.1454_1456del p.E485del | In Frame Del (DEL) | VAF 20/160 reads (13%) | called by pindel, varscan2
- BCR | c.1866G>A p.L622= | Silent (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- EIF5 | c.1239A>G p.K413= | Silent (SNP) | VAF 17/345 reads (5%) | catalogued as COSV53685442; called by muse, mutect2
- EPAS1 | c.2568C>T p.L856= | Silent (SNP) | VAF 57/701 reads (8%) | catalogued as COSV55384746; called by muse, mutect2
- FAM180A | c.426C>T p.G142= | Silent (SNP) | VAF 31/310 reads (10%) | catalogued as rs754102381; called by muse, mutect2
- GPR108 | c.597C>T p.L199= | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- MAGEB3 | c.114A>T p.V38= | Silent (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- CDK10 | c.87+794T>A | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- ENPP1 | c.1893+38T>C | Intron (SNP) | VAF 26/416 reads (6%) | called by muse, mutect2
- PGC | c.-11G>A | 5'UTR (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
